Gene-level copy-number profile of tumor specimen C3L-01156-01 (profiled together with C3L-01156-02) from CPTAC case C3L-01156, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 57.5 years (20,999 days).
Specimen C3L-01156-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8c386429-6949-4f04-800d-d77464664e81.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01156-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/9daea034-a27f-47bb-94b8-29c42d0a91b6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 135; copy number 1: 57; copy number 2: 5,822; copy number 3: 1,792; copy number 4: 43,482; copy number 5: 2,464; copy number 6: 5,063; copy number 7: 1; copy number 8: 85; copy number 10: 1; copy number 323: 4; copy number 464: 1.

Homozygous deletions (total copy number 0; autosomes only): 135 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,895,800–30,990,572, 135 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,933,699–55,255,635, 5 genes, copy number 323–464: AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1.
- chr22:18,733,914–18,757,906, 1 gene, copy number 10: FAM230E.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
